Somatic mutation profile of tumor specimen HCM-BROD-0012-C71-01A (aliquot HCM-BROD-0012-C71-01A-01D-A768-36) from HCMI case HCM-BROD-0012-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 56.8 years (20,744 days).
Specimen HCM-BROD-0012-C71-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c3fee543-4c7d-47df-a2e9-b23b720d636c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0012-C71-10A (Blood Derived Normal), aliquot HCM-BROD-0012-C71-10A-01D-A768-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b315e675-7b7c-4461-bd52-cd976459cb88

The open-access MAF lists 66 somatic variants for this specimen: 39 protein-altering or splice-affecting, 16 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 16, Splice Site 5, Intron 4, 3'UTR 3, RNA 3, Nonsense Mutation 1, 5'UTR 1, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP7A | c.1996G>A p.G666R | Missense Mutation (SNP) | VAF 108/301 reads (36%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.979); catalogued as rs797045344, CM109533; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- GLA | c.1066C>T p.R356W | Missense Mutation (SNP) | VAF 78/172 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.705); catalogued as rs104894827, CM890057; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTPN11 | c.188A>G p.Y63C | Missense Mutation (SNP) | VAF 79/182 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121918459, CM013416, COSV61007856; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AL645922.1 | c.374C>T p.S125L | Missense Mutation (SNP) | VAF 181/434 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs753059312, COSV54960912; called by muse, mutect2, varscan2
- ALG5 | c.496G>A p.G166R | Missense Mutation (SNP) | VAF 41/144 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV99523601; called by muse, mutect2, varscan2
- ARSF | c.164C>T p.T55M | Missense Mutation (SNP) | VAF 86/221 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs201726785; called by muse, mutect2, varscan2
- CBY2 | c.1249G>A p.V417M | Missense Mutation (SNP) | VAF 65/154 reads (42%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV60119502; called by muse, mutect2, varscan2
- CNTNAP5 | c.2104C>T p.R702W | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1207750958, COSV70472432, COSV70483251; called by muse, mutect2, varscan2
- EXOC3L1 | c.88C>T p.R30W | Missense Mutation (SNP) | VAF 59/135 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs139069832; called by muse, mutect2, varscan2
- FAM186A | c.580del p.I194Yfs*16 | Frame Shift Del (DEL) | VAF 11/44 reads (25%) | catalogued as rs1260976214; called by mutect2, pindel, varscan2
- ISG20 | c.353G>A p.R118H | Missense Mutation (SNP) | VAF 54/141 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as rs549880749, COSV60143590; called by muse, mutect2, varscan2
- KANK4 | c.901G>A p.E301K | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.083); catalogued as rs759887895; called by muse, mutect2, varscan2
- KCNH3 | c.2072G>A p.R691H | Missense Mutation (SNP) | VAF 110/249 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs763321479, COSV57793215; called by muse, mutect2, varscan2
- NF2 | c.1341-2A>C p.X447_splice | Splice Site (SNP) | VAF 119/358 reads (33%) | catalogued as CS115647, COSV58527036; called by muse, mutect2, varscan2
- PCDH15 | c.4212-2A>C p.X1404_splice | Splice Site (SNP) | VAF 74/212 reads (35%) | catalogued as COSV57412888; called by muse, mutect2, varscan2
- RHBDL1 | c.341C>T p.A114V (on ENST00000219551 / NM_001318733.2; = p.A49V on NM_001278720.2) | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1176173464; called by muse, mutect2, varscan2
- STARD6 | c.545C>T p.S182L | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.259); catalogued as COSV100323564; called by muse, mutect2, varscan2
- TNIP2 | c.523C>T p.R175* | Nonsense Mutation (SNP) | VAF 59/153 reads (39%) | catalogued as rs556774838; called by muse, mutect2, varscan2
- TPTE2 | c.593A>G p.E198G (on ENST00000400230 / NM_199254.2; = p.E121G on NM_130785.3) | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.477); catalogued as rs1305168994; called by muse, mutect2, varscan2
- ZNF234 | c.1169A>G p.H390R | Missense Mutation (SNP) | VAF 81/265 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs753238363, COSV70604230; called by muse, mutect2, varscan2
- ZNF536 | c.1447G>A p.G483R | Missense Mutation (SNP) | VAF 37/50 reads (74%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.708); catalogued as rs755613678, COSV100835485, COSV100835753; called by muse, mutect2, varscan2
- AP4E1 | c.251T>A p.L84H | Missense Mutation (SNP) | VAF 13/181 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2
- BOK | c.45G>A p.M15I | Missense Mutation (SNP) | VAF 58/184 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ENOX2 | c.340+1_340+2del p.X114_splice (on ENST00000338144 / NM_001382520.1; = p.X85_splice on NM_006375.3 and 2 other RefSeq transcripts) | Splice Site (DEL) | VAF 21/74 reads (28%) | called by mutect2, pindel, varscan2
- GLUD1 | c.880G>A p.G294R | Missense Mutation (SNP) | VAF 64/181 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- GNAL | c.547-1G>A p.X183_splice (on ENST00000269162 / NM_001142339.3; = p.X260_splice on NM_182978.4) | Splice Site (SNP) | VAF 39/115 reads (34%) | called by muse, mutect2, varscan2
- HOXA10 | c.941C>A p.P314Q | Missense Mutation (SNP) | VAF 144/378 reads (38%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- KATNAL1 | c.1013-1G>A p.X338_splice | Splice Site (SNP) | VAF 24/66 reads (36%) | called by muse, mutect2, varscan2
- LCMT1 | c.371C>T p.P124L | Missense Mutation (SNP) | VAF 36/124 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- LRTM2 | c.706G>A p.G236R | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- LUC7L2 | c.1024G>C p.D342H | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- MYH4 | c.4389G>T p.K1463N | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NPIPB15 | c.1157C>T p.P386L | Missense Mutation (SNP) | VAF 192/966 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.351); called by muse, varscan2
- PSMC5 | c.220G>A p.G74R | Missense Mutation (SNP) | VAF 59/107 reads (55%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- QKI | c.325dup p.T109Nfs*6 | Frame Shift Ins (INS) | VAF 55/112 reads (49%) | called by mutect2, pindel, varscan2
- RAB40AL | c.454T>G p.F152V | Missense Mutation (SNP) | VAF 158/376 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- RPIA | c.677G>A p.S226N | Missense Mutation (SNP) | VAF 43/101 reads (43%) | SIFT tolerated (0.56); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- SHROOM4 | c.220C>A p.L74I | Missense Mutation (SNP) | VAF 101/286 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TIMM29 | c.388T>A p.C130S | Missense Mutation (SNP) | VAF 99/241 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- ABCA1 | c.1320G>A p.L440= | Silent (SNP) | VAF 187/239 reads (78%) | called by muse, mutect2, varscan2
- CLEC17A | c.714G>A p.Q238= | Silent (SNP) | VAF 45/103 reads (44%) | called by muse, mutect2, varscan2
- DOC2B | c.471C>T p.D157= | Silent (SNP) | VAF 35/109 reads (32%) | called by muse, mutect2, varscan2
- EFCC1 | c.315C>T p.S105= | Silent (SNP) | VAF 29/81 reads (36%) | called by muse, mutect2, varscan2
- GUF1 | c.99G>A p.A33= | Silent (SNP) | VAF 71/168 reads (42%) | catalogued as COSV55785447; called by muse, mutect2, varscan2
- ITGA11 | c.3084C>T p.D1028= | Silent (SNP) | VAF 51/137 reads (37%) | catalogued as rs61729773; called by muse, mutect2, varscan2
- KCNB2 | c.1524C>T p.F508= | Silent (SNP) | VAF 74/168 reads (44%) | catalogued as rs752821146, COSV73049012; called by muse, mutect2, varscan2
- MCF2L | c.3087C>T p.D1029= (on ENST00000375608; = p.D997= on NM_024979.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 24/76 reads (32%) | catalogued as rs781264646, COSV56181082; called by muse, mutect2, varscan2
- MEX3D | c.1212C>T p.A404= | Silent (SNP) | VAF 30/70 reads (43%) | catalogued as rs1415261817; called by muse, mutect2, varscan2
- MRI1 | c.1056C>T p.A352= (on ENST00000040663 / NM_001031727.4; = p.A305= on NM_032285.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 31/112 reads (28%) | called by muse, mutect2, varscan2
- OR51F1 | c.576T>C p.D192= | Silent (SNP) | VAF 43/98 reads (44%) | called by muse, mutect2, varscan2
- OR5M8 | c.111G>A p.T37= | Silent (SNP) | VAF 39/136 reads (29%) | catalogued as rs376992051; called by muse, mutect2, varscan2
- PTPRB | c.5454G>A p.A1818= | Silent (SNP) | VAF 20/50 reads (40%) | catalogued as rs369428514; called by muse, mutect2, varscan2
- SIPA1L2 | c.1479G>A p.G493= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as rs1558235290; called by mutect2, varscan2
- TANC1 | c.5154C>T p.P1718= | Silent (SNP) | VAF 91/199 reads (46%) | catalogued as COSV55096794; called by muse, mutect2, varscan2
- UPF1 | c.1764G>A p.L588= (on ENST00000599848 / NM_001297549.2; = p.L577= on NM_002911.4) | Silent (SNP) | VAF 39/88 reads (44%) | catalogued as COSV53198280; called by muse, mutect2, varscan2
- ACSF3 | c.*1242C>T | 3'UTR (SNP) | VAF 75/176 reads (43%) | called by muse, mutect2, varscan2
- CCDC74A | c.250+190G>A | Intron (SNP) | VAF 90/233 reads (39%) | called by muse, mutect2, varscan2
- CPLANE1 | c.*264G>T | 3'UTR (SNP) | VAF 6/98 reads (6%) | called by muse, mutect2
- EPB41 | c.1845+36T>G | Intron (SNP) | VAF 97/232 reads (42%) | called by muse, mutect2, varscan2
- FASTKD2 | c.1899-18G>A | Intron (SNP) | VAF 84/240 reads (35%) | called by muse, mutect2, varscan2
- GVINP1 | n.4279G>C | RNA (SNP) | VAF 49/154 reads (32%) | called by muse, mutect2, varscan2
- H2AZ2 | c.*15C>T | 3'UTR (SNP) | VAF 34/80 reads (43%) | called by muse, mutect2, varscan2
- MMP26 | c.-145+92644T>A | Intron (SNP) | VAF 67/168 reads (40%) | called by muse, mutect2, varscan2
- PPIL6 | c.-9G>A | 5'UTR (SNP) | VAF 10/16 reads (63%) | called by muse, varscan2
- XIST | n.10941T>A | RNA (SNP) | VAF 45/86 reads (52%) | called by muse, mutect2, varscan2
- XIST | n.7432_7433del | RNA (DEL) | VAF 70/220 reads (32%) | catalogued as rs1047292168; called by mutect2, pindel, varscan2
